Gene-level copy-number profile of tumor specimen HTMCP-02-06-01158-01B from CGCI case HTMCP-02-06-01158, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 67.8 years (24,771 days).
Specimen HTMCP-02-06-01158-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 33ea520b-e089-47ba-9e8d-c4646d42c5be.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-06-01158-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/b84128cc-9e2e-4634-9359-0a7a3bc541c8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 6,529; copy number 2: 25,059; copy number 3: 19,908; copy number 4: 4,250; copy number 5: 793; copy number 6: 842; copy number 7: 219; copy number 8: 315; copy number 9: 290; copy number 10: 230; copy number 11: 187; copy number 12: 107; copy number 13: 3; copy number 14: 75; copy number 15: 31; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,341,826–8,226,614, 59 genes (within-gene range 0–1): AC130360.1, ZNF705G, DEFB108C, DEFB4B, HSPD1P3, DEFB103B, SPAG11B, DEFB104B, DEFB106B, DEFB105B, DEFB107B, PRR23D1, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P, AC134684.1, AC084121.1, OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1, AC105233.4, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1.
- chr8:37,559,992–37,599,858, 2 genes: AC124067.3, AC124067.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,093 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,956,975–44,674,481, 210 genes, copy number 10–15 (broad region; genes not listed).
- chr1:146,472,566–148,255,012, 48 genes, copy number 7–8 (within-gene range 4–8): HYDIN2, RNA5SP536, AC241929.1, NBPF12, PFN1P8, AC244394.3, AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57.
- chr1:149,754,301–151,249,536, 85 genes, copy number 8 (broad region; genes not listed).
- chr1:152,168,125–152,445,456, 1 gene, copy number 6 (within-gene range 3–6): FLG-AS1.
- chr1:152,212,076–155,859,400, 206 genes, copy number 6–9 (within-gene range 3–9) (broad region; genes not listed).
- chr1:175,944,831–176,207,286, 1 gene, copy number 6 (within-gene range 4–6): COP1.
- chr1:176,017,277–178,921,841, 37 genes, copy number 6: AL590723.1, AL591043.2, U7, AL359265.2, RNU2-12P, AL359265.1, AL591043.1, MORF4L1P7, PAPPA2, PTP4A1P7, AL031290.1, ASTN1, MIR488, BRINP2, LINC01645, AL136114.1, LINC01741, SEC16B, CRYZL2P-SEC16B, CRYZL2P, AL359075.1, RASAL2-AS1, RASAL2, AL160281.1, AL365357.1, CLEC20A, Metazoa_SRP, TEX35, C1orf220, RNA5SP69, AL137796.1, MIR4424, AL449106.1, RALGPS2, PTPN2P1, SNORA63, ANGPTL1.
- chr1:188,013,642–205,457,091, 285 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr1:216,503,246–230,007,195, 295 genes, copy number 5–11 (broad region; genes not listed).
- chr1:231,018,958–231,040,254, 1 gene, copy number 9 (within-gene range 3–9): FAM89A.
- chr5:58,198–45,895,970, 678 genes, copy number 5–7 (broad region; genes not listed).
- chr7:37,032–31,330,896, 543 genes, copy number 5–6 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 7: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 7: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes, copy number 7 (within-gene range 4–7): TRGV5P, TRGV5, TRGV4.
- chr14:22,163,238–22,501,663, 51 genes, copy number 5: TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr16:33,533,816–33,570,935, 4 genes, copy number 8: AC136944.1, AC136944.2, AC136944.4, AC136944.3.
- chr20:13,714,322–13,996,443, 4 genes, copy number 5 (within-gene range 4–5): ESF1, NDUFAF5, SEL1L2, RNU6-278P.
- chr20:26,135,983–26,251,546, 2 genes, copy number 5 (within-gene range 4–5): AL121904.2, MIR663AHG.
- chr20:26,208,186–26,208,278, 1 gene, copy number 5: MIR663A.
- chr20:49,812,713–50,153,637, 12 genes, copy number 5 (within-gene range 3–5): SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1.
- chr20:52,972,358–54,173,986, 20 genes, copy number 8–9: TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1.
- chr20:57,599,695–57,712,780, 4 genes, copy number 14: AL035541.1, ZBP1, PMEPA1, NKILA.
- chr20:57,957,126–63,891,545, 173 genes, copy number 7–20 (broad region; genes not listed).
- chr21:24,154,871–24,192,924, 1 gene, copy number 5: AP000470.1.
- chr21:25,361,821–25,772,460, 15 genes, copy number 8: RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2.
- chr21:30,089,717–30,480,367, 19 genes, copy number 6 (within-gene range 4–6): AF096876.1, CLDN17, LINC00307, CLDN8, RPL8P2, KRTAP24-1, KRTAP25-1, KRTAP26-1, KRTAP27-1, KRTAP23-1, KRTAP13-6P, KRTAP13-2, MIR4327, KRTAP13-1, KRTAP13-3, KRTAP13-4, KRTAP13-5P, KRTAP15-1, KRTAP19-1.
- chr21:32,277,863–32,393,960, 6 genes, copy number 7 (within-gene range 4–7): MIS18A-AS1, MRAP, MRAP-AS1, URB1, SNORA80A, URB1-AS1.
- chr21:33,229,901–36,576,569, 79 genes, copy number 5–9 (broad region; genes not listed).
- chr21:36,698,773–46,691,226, 292 genes, copy number 5–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,283. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
